Gene-level copy-number profile of tumor specimen HCM-SANG-1299-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-1299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1299-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 76f860c1-2318-43a9-b21b-af28d08a4024.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1299-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/6648ec30-9937-475c-ac8c-ab7c6c5e9460

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,976; copy number 2: 41,556; copy number 3: 1,433; copy number 4: 216; copy number 5: 119; copy number 6: 329; copy number 7: 156; copy number 10: 47; copy number 11: 5; copy number 14: 34; copy number 27: 3; copy number 44: 37.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 730 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,564,029–56,394,094, 254 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).
- chr9:29,824,742–29,826,711, 1 gene, copy number 5: ME2P1.
- chr9:33,290,512–36,677,683, 159 genes, copy number 5–6 (broad region; genes not listed).
- chr11:45,355,371–46,594,125, 40 genes, copy number 27–44: LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1.
- chr17:30,115,521–30,186,475, 1 gene, copy number 5 (within-gene range 3–5): NSRP1.
- chr17:30,144,062–30,672,789, 25 genes, copy number 5: AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1.
- chr17:36,861,674–41,836,260, 250 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,120. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
